OHSU case 2080 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc0e24c1-ea5c-424c-897a-0727c3e9ac3c

Demographics
Vital status: Dead.

Diagnoses (1)
1. Atypical chronic myeloid leukemia, BCR/ABL negative: ICD-O-3 morphology code: 9876/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 85.0 years (31,046 days); Days to last follow up: 493 days (1.3 years).

Biospecimens (2 samples)
- Sample 4769D: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample 4769R: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
